Somatic mutation profile of tumor specimen TCGA-YU-A912-01A (aliquot TCGA-YU-A912-01A-11D-A435-10) from TCGA case TCGA-YU-A912, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 34.4 years (12,552 days).
Specimen TCGA-YU-A912-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f38bf71-c46f-4564-b28b-3dd5cc76681a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A912-10A (Blood Derived Normal), aliquot TCGA-YU-A912-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c0bafab-e3cf-437a-96aa-7ac94bdae402

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 5'UTR 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5482G>A p.V1828M | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1259717910; called by muse, mutect2, varscan2
- FRS3 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1188934330; called by muse, mutect2
- TRIP12 | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs1298864132, COSV99390690; called by muse, mutect2, varscan2
- EMID1 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GNAT3 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- KIAA2013 | c.1737T>G p.H579Q | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCLO | c.15263T>C p.L5088P | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RSPO2 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- UBN1 | c.3224C>G p.T1075R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASL | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZFHX4 | c.9350C>T p.S3117F | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ABCB8 | c.39C>T p.G13= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs777805590; called by muse, varscan2
- UBN1 | c.153C>G p.L51= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-60G>A | 5'UTR (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- HDGF | c.*14A>C | 3'UTR (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- SPEN | c.-14G>T | 5'UTR (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
